HCMI case HCM-BROD-0095-C15 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/05f41641-ee22-4d41-bb87-2bfa47cd983f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Dead; Days to death: 272 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Esophagus, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 51.5 years (18,799 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T3; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Liver / Lung, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 13 days; Days to treatment end: 67 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 76 days; Days to treatment end: 104 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ramucirumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 76 days; Days to treatment end: 104 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 146 days; Days to treatment end: 188 days.
   Treatment given: Treatment type: Radiation, 3D Conformal; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 202 days; Days to treatment end: 215 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; Surgery, NOS, for initial diagnosis.

Follow-up (5 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 17 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 17 days.
- Days to follow up: 267 days; Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 250.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: GERD.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol intensity: Non-Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0095-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0095-C15-06A-01-S1-HE: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0095-C15-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 40; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0095-C15-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0095-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
